Somatic mutation profile of tumor specimen 0DSHT8 from CCDI case PBCIAP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Small intestine, NOS; Age at diagnosis: 13.2 years (4,804 days).
Specimen 0DSHT8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d29ea70-2015-4a8b-94fa-3805e5e9ade1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b50ba100-22bc-429d-8aa5-7d41a0091ae9

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC30 | c.1247A>C p.D416A (on ENST00000340612; = p.D373A on NM_001080850.3) | Missense Mutation (SNP) | VAF 58/1232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59604411; called by muse, mutect2
- TMEM94 | c.968T>G p.L323R | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
